Somatic mutation profile of tumor specimen TARGET-10-PARNSP-09A (aliquot TARGET-10-PARNSP-09A-01D) from TARGET case TARGET-10-PARNSP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,206 days).
Specimen TARGET-10-PARNSP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 669b737a-246a-4855-866b-e21653a472a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNSP-10A (Blood Derived Normal), aliquot TARGET-10-PARNSP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e55fcad-cbef-42ef-b05d-7c20bb5475d2

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Ins 3, Nonsense Mutation 2, RNA 2, Frame Shift Del 1, In Frame Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1A | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938487720, COSV52362588; called by muse, mutect2, varscan2
- ANKRD12 | c.5353C>T p.R1785W | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750074114, COSV50839442; called by muse, mutect2, varscan2
- ARHGEF38 | c.1655T>A p.L552H | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV70365209; called by muse, mutect2, varscan2
- FBN2 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99330494; called by muse, mutect2
- GLI2 | c.1442C>T p.T481M (on ENST00000361492 / NM_001374353.1; = p.T498M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894445064, COSV100083410; called by muse, mutect2
- GRM4 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1373099968, COSV100946318; called by muse, mutect2
- KDM3A | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762729197, COSV57219599; called by muse, mutect2, varscan2
- KIAA1217 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs534553518, COSV56821317; called by muse, mutect2, varscan2
- KIF1A | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs531522772, COSV57495592, COSV99064879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP10-8 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV58167003; called by muse, mutect2, varscan2
- LEF1 | c.952delinsCC p.V318Pfs*3 | Frame Shift Ins (INS) | VAF 40/134 reads (30%) | catalogued as COSV54470262, COSV54471390; called by pindel, varscan2*
- MMP15 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs759067050, COSV54681066; called by muse, mutect2, varscan2
- MYH13 | c.1048G>T p.G350W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757492935, COSV52820642, COSV52838409; called by muse, mutect2, varscan2
- PIK3R1 | c.1728_1729insTGGTGCTCC p.T576_R577insWCS (on ENST00000521381 / NM_181523.3; = p.T306_R307insWCS on NM_181504.4) | In Frame Ins (INS) | VAF 16/130 reads (12%) | catalogued as COSV57136309; called by mutect2, pindel
- RELN | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV59025810; called by muse, varscan2
- RHAG | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV57705705; called by muse, mutect2, varscan2
- SLC16A14 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1406286210, COSV54620536; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- TMEM145 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs998154830, COSV56627096; called by muse, mutect2, varscan2
- ZFAND3 | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV54726283, COSV54731925; called by muse, mutect2, varscan2
- ZSCAN20 | c.1106T>C p.F369S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63684020; called by muse, mutect2, varscan2
- BRSK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTCF | c.1125dup p.E376Rfs*33 | Frame Shift Ins (INS) | VAF 43/93 reads (46%) | called by mutect2, pindel, varscan2
- FBN1 | c.6121C>T p.P2041S | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRT7 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LEF1 | c.490_493delinsGGGCCACTG p.H164Gfs*85 | Frame Shift Ins (INS) | VAF 10/21 reads (48%) | called by pindel, varscan2*
- COL5A1 | c.1638G>A p.A546= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs775508023, COSV65666262; ClinVar: likely benign; called by muse, mutect2
- NEUROD6 | c.819G>A p.L273= | Silent (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- TTC25 | c.213G>A p.E71= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- ZBTB20 | c.483C>T p.G161= (on ENST00000474710 / NM_001164342.2; = p.G88= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs772400910, COSV61849791; called by muse, mutect2, varscan2
- C5orf60 | n.399G>A | RNA (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- NPIPB1P | n.280G>A | RNA (SNP) | VAF 39/147 reads (27%) | catalogued as rs780843608; called by muse, mutect2, varscan2
- SRR | c.*1382C>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- TRMT10B | c.-26G>A | 5'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
